Somatic mutation profile of tumor specimen MP2PRT-PATWWZ-TMP1-A (aliquot MP2PRT-PATWWZ-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PATWWZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,021 days).
Specimen MP2PRT-PATWWZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5d30df1-427e-41d5-9782-6ee617c5d3d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATWWZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATWWZ-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e01bebf-49c9-43b5-8e8f-0e122f74db73

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAAM2 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 196/613 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs746541722, COSV51315319; called by muse, mutect2, varscan2
- ETV1 | c.731G>T p.S244I | Missense Mutation (SNP) | VAF 136/454 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.051); catalogued as rs180893787; called by muse, mutect2, varscan2
- PAK5 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 175/583 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1018346655, COSV62026383, COSV62026965; called by muse, mutect2, varscan2
- SDR42E2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 150/661 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1011293137, COSV58307937; called by muse, mutect2, varscan2
- SLITRK4 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV62024575; called by muse, mutect2, varscan2
- SYNPO2 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 126/415 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61108133; called by muse, mutect2, varscan2
- TRPM3 | c.2960G>A p.R987H (on ENST00000357533 / NM_001366142.2; = p.R830H on NM_020952.6) | Missense Mutation (SNP) | VAF 147/413 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1432206553, COSV62586228; called by muse, mutect2, varscan2
- CREBBP | c.5519_5540delinsAGGTCCCCT p.V1840Efs*29 | Frame Shift Del (DEL) | VAF 152/847 reads (18%) | called by pindel, varscan2*
- DDX60L | c.2407C>G p.Q803E | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TERF2 | c.1606A>C p.M536L | Missense Mutation (SNP) | VAF 97/404 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ZFHX4 | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 155/433 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- PHC1 | c.1185C>T p.I395= | Silent (SNP) | VAF 170/841 reads (20%) | called by muse, mutect2, varscan2
- SPANXD | c.132A>G p.T44= | Silent (SNP) | VAF 193/610 reads (32%) | called by muse, mutect2, varscan2
- SQOR | c.303T>C p.R101= | Silent (SNP) | VAF 29/543 reads (5%) | catalogued as rs372185368; called by muse, mutect2
